Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7090, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7090-01A (Primary Tumor).

** Case imported from legacy computer system. The format of this report does not match the original case. **
** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. **

SUPPLEMENTAL REPORT

DIAGNOSIS:

- (B) HARD PALATE:
Bone and mucosa, no tumor present.

Entire report and diagnosis completed by: [REDACTED]

DIAGNOSIS

- (A) BUCCAL FAT BIOPSY:
Adipose tissue, no tumor present.
- (B) BONE FROM POSTERIOR WALL OF MAXILLA:
Tissue submitted for decalcification. Supplemental report will follow.
- (C) PARTIAL MAXILLECTOMY AND HEMIPALATECTOMY:
INVASIVE SQUAMOUS CELL CARCINOMA, GRADE 2, PRESENCE OF PERINEURAL INVASION, THICKNESS AREA OF TUMOR 2.5 CM.
Tissue submitted for decalcification. Supplemental report will follow.
Bone margins of resection submitted for decal. Supplemental report will follow.
- (D) HARD PALATE:
Pending decalcification.
- (E) MARGIN MEDIAL LINE:
Salivary gland, no tumor present.
- (F) MUCOSA FROM MAXILLARY SINUS:
Respiratory mucosa, no tumor present.
- (G) INFERIOR TURBINATE:
Respiratory mucosa, no tumor present.
- (H) TISSUE ALONG NASAL CAVITY:
Mucous glands, no tumor present.
- (I) TEETH:
Teeth (gross diagnosis only).

Entire report and diagnosis completed by: [REDACTED]

Source: NCI Genomic Data Commons file 88abdb04-cdc8-4f5f-89de-95b668717912 (TCGA-CV-7090.7E4141D1-7443-46BC-8D11-A5DFF690CD5F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).